Surgical pathology report (de-identified scan), TCGA case TCGA-T3-A92M, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Molecular Response, specimen TCGA-T3-A92M-01A (Primary Tumor).

[page 1 of 5]
DA31F2A

ICD O. 3
Carcinoma, squamous cell NOS 8074/3
Site: Lung NOS C32.9
9/3/20/14

Subject Number:

Retain original and email/fax copy to

Sample Collection Date:	  /   /     :   :     -                      	Procured by: _____
Time of Tumor Sample Excision (24 hour clock):	  :   :          	Time Zone: _____

FROZEN SAMPLES BATCH SHIPPED (dry ice); FRESH TUMOR SAMPLE, IF COLLECTED, SHIPPED ON DAY OF COLLECTION

Frozen Tumor (Required)

Weight of Tissue: 250 mg
(tissue weight must be ≥ 100 mg)

Time placed in dewar:
(24 hour clock)

$$\text{H} \quad \text{H} \quad \cdot \cdot \cdot \quad \text{M} - \text{M}$$

Fresh Tumor (Optional) ☐ N/A

Locate the "Fresh Tumor" label in the kit and affix to the 15ml tube (sent separately). Place any remaining tumor tissue into the 15ml conical tube containing

Weight of Tissue: 100 mg
(no min. weight specified)

Time placed in
(24 hour clock)

Lot Number of

H H : M M

WHOLE BLOOD SAMPLE (Required) - BATCHED SHIPPED FROZEN (dry ice)

Sample Collection Date:	                         	Procured by: _____
Time of Blood Sample Collection (24 hour clock):	             	Time Zone: _____

1-10ml EDTA tube. Fill tube completely and mix by gentle inversion at least 8-10 times. Freeze sample on dry ice or place in vapor phase dewar.

Time placed in dry ice/dewar:
(24 hour clock)

$$H \quad H : M \quad M$$

BASIC PATHOLOGICAL INFORMATION

Clinical Diagnosis:
(Ex. Lung Cancer)

Larynx Cancer
HEAD/NECK CANCER

Source of Specimen:
(Ex. Right Lung)

LARYNX

[page 2 of 5]
Confidential

Tissue/Blood Requisition Form

Site ID:

Subject Number:

Diagnostic Slides (Required) - SLIDES BATCHED SHIPPED (ambient)

From the diagnostic FFPE block, cut 3 slides with one section ~ 4-5µm on each slide. Label the frosted tip of the slide in pencil with the sample ID (located on the label at the top of this form). Record the ID number of the diagnostic histology cassette and the number of slides. H&E stain the slides and store in a slide mailer.

Diagnostic Histology Cassette ID

Number of Slides Cut 3

Refer to Study Manual for detailed specimen processing and shipping instructions. (* denotes required samples)

Specimen	Collection Vessel	Transfer Tube	Shipping Status
Frozen Tumor*	None	Cryovial	Same Day – Dry Ice
Frozen Blood*	1-10ml EDTA	None	Same Day – Dry Ice
Fresh Tumor	None	15ml-	Same Day – Refrigerated
Diagnostic Slides*	Histology Cassette	SuperFrost Slides	5-Slide Mailer—Batch

When FROZEN and FRESH samples are ready for shipment please notify by Email notification: _____
At this time, please also provide your Sample Manifest.

When the Diagnostic slides are ready for shipment please notify by Email notification: _____ At this time, please also provide your Sample Manifest.

DO NOT RETURN EMPTY CONTAINERS TO

White copy-Retain for your Records

Yellow copy-send to pathology for diagnostic slides

[page 3 of 5]
Surgical Pathology Final Report
Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

Final Diagnosis

Total laryngectomy and partial pharyngectomy:

Moderately-differentiated squamous cell carcinoma.

Histologic grade: G2.

Tumor site: Glottic, subglottic, supraglottic.

Tumor size: 4.1 cm.

Tumor laterality: Predominantly right-sided.

Tumor extent: Tumor invades through the outer cortex of the thyroid cartilage.

Margins: See below.

AJCC Pathologic stage: **pT4a pN2c.**

Inferior anterior tracheal margin, excision with frozen section:

No invasive or in situ carcinoma is identified.

Right lateral pharyngeal wall margin, excision with frozen section:

No invasive or in situ carcinoma is identified.

Left lateral pharyngeal wall margin, excision with frozen section:

No invasive or in situ carcinoma is identified.

Mucosa base of tongue margin, excision with frozen section:

No invasive or in situ carcinoma is identified.

Right level 2B lymph nodes:

Three (3) of three (3) lymph nodes are involved by metastatic carcinoma.

Extracapsular extension is present.

All nodes are less than 3 cm in size.

Left level 2A lymph nodes:

One (1) lymph node is present and is involved by metastatic carcinoma.

Extracapsular extension is present.

The node is 1.7 cm in size.

Salivary gland:

Benign salivary gland tissue.

[REDACTED]

[page 4 of 5]
Surgical Pathology Final Report

Temporary Copy

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Clinical Information

Laryngeal cancer.

Frozen Section Diagnosis

Time in: Time out:

FSB, Right lateral pharyngeal margin: Mild dysplasia with HPV effect. Negative for invasive carcinoma.

FSC, Left lateral pharyngeal wall margin: Negative for malignancy.

FSD, Inferior anterior tracheal margin: Negative for malignancy.

FSE, Mucosal base of tongue: Negative for malignancy.

Operating Room Consultation

Time in: Time out:

Tissue for [REDACTED] Received is a laryngectomy specimen. Margins closest to mass inked. Submucosal tumor samples for [REDACTED]

Gross Description

"A, Total laryngectomy and partial pharyngectomy." Received is a 7.7 x 5.2 x 4.6 cm larynx. The tracheal margin will be inked orange. Attached to the right side of the larynx is a 3.0 x 2.1 cm portion of pharynx. The pharyngeal soft tissue margin has been previously inked black. The tracheal and pharyngeal margins will be shaved and submitted in toto. There is a 4.1 x 3.4 cm mass which grossly appears to be in the wall of the right side of the larynx. The anterior aspect of the larynx adjacent to this mass to include a 4.1 x 3.5 x 1.5 cm right lobe of thyroid will be inked yellow. The mass grossly appears to abut the anterior aspect of the right side of the larynx. The mass does not grossly appear to extend into the attached portion of right lobe of thyroid. The mass grossly appears to be confined to the submucosa of the larynx and does not grossly appear to involve the right or left vocal cords. The cut surface of the portion of attached lobe of thyroid is red-tan and no masses or lesions are grossly identified in the portion of attached thyroid lobe. "A1," left half of tracheal margin; "A2," right half of tracheal margin; "A3," left pharyngeal soft tissue margin; "A4," posterior pharyngeal soft tissue margin; "A5," right pharyngeal soft tissue margin; "A6-A7," full-thickness sections of the mass; "A6," tracheal mucosa aspect; "A7," anterior wall of trachea aspect to include portion of lobe of thyroid; "A8," mass to include anterior aspect of trachea; "A9," random sections of mass with subglottic portion of attached tracheal mucosa; "A10," right true and false vocal cords; "A11," anterior commissure; "A12," left true and false vocal cords; "A13," left pyriform sinus; "A14," epiglottis; "A15," right pyriform sinus.

"B, FSB." Received is frozen section control tissue. Tea bag. "FSB," all.

"C, FSC." Received is frozen section control tissue. Tea bag. "FSC," all.

"D, FSD." Received is frozen section control tissue. "FSD," all.

"E, FSE." Received is frozen section control tissue. "FSE," all.

"F, Right level 2B." Received are 3 tan tissue fragments ranging from 1.0 to 1.4 cm in greatest dimension. On sectioning, there are 3 possible lymph nodes ranging from 0.8 to 1.1 cm. Random sections of all of the lymph nodes will be submitted. "F," representative.

"G, Left level 2A." Received is a 1.7 x 1.3 x 0.6 cm lymph node. The cut surface is gray-tan. The specimen will be bisected and submitted in toto. "G," all.

"H, Salivary gland." Received is a 4.1 x 2.5 x 1.5 cm salivary gland. The specimen will be inked black. The cut surface of the gland is tan and lobulated. No masses or lesions are grossly identified on the gland. "H1-H3," representative.

[page 5 of 5]
Surgical Pathology Final Report

Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9f1512fd-34a7-46e3-b79e-159c1f7374ed (TCGA-T3-A92M.8731CB50-7625-484B-9858-AF17BDA31F2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).